Somatic mutation profile of tumor specimen TCGA-14-1825-01A (aliquot TCGA-14-1825-01A-01D-1494-08) from TCGA case TCGA-14-1825, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.3 years (25,684 days).
Specimen TCGA-14-1825-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1df70f6a-ce8f-4a99-9966-51bfba1a845d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1825-10A (Blood Derived Normal), aliquot TCGA-14-1825-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60be0185-e60d-4d88-b7d5-e1ba22ef928a

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 9, Nonsense Mutation 2, 5'UTR 2, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 27/72 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 39/82 reads (48%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.905A>C p.H302P | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55540815; called by muse, mutect2, varscan2
- AARS1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55749833; called by muse, mutect2, varscan2
- ACR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs777620745, COSV53360385; called by muse, mutect2, varscan2
- APBB1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.099); catalogued as COSV54973401, COSV54979369; called by muse, mutect2, varscan2
- BPIFA2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as COSV53612926; called by muse, mutect2
- CCDC144A | c.2596A>C p.I866L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100138729; called by muse, mutect2, varscan2
- CFP | c.833C>A p.T278N | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55951571; called by muse, mutect2, varscan2
- CLCNKB | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 107/248 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201540273, CM004244, COSV65161667; called by muse, mutect2, varscan2
- CYSLTR2 | c.658T>A p.C220S | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV56167142; called by muse, mutect2, varscan2
- DCAF12L1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 60/68 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421605; called by muse, mutect2, varscan2
- DUSP22 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV60532022; called by muse, mutect2, varscan2
- HFE | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV58514096; called by muse, mutect2, varscan2
- HOXC13 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.053); catalogued as COSV54498145; called by muse, mutect2
- IGLV3-9 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs1244079314; called by muse, mutect2, varscan2
- KIF4B | c.3557C>A p.A1186D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV70528446, COSV70531810; called by muse, mutect2, varscan2
- KMT2D | c.15210T>A p.Y5070* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV56491819; called by muse, mutect2, varscan2
- L1TD1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as rs778590430, COSV63133564; called by muse, mutect2, varscan2
- MAGEA10 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV54885674; called by muse, mutect2, varscan2
- MED22 | c.293T>C p.I98T | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1355030719, COSV59300329; called by muse, mutect2, varscan2
- MLYCD | c.427C>G p.H143D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV52306876; called by muse, mutect2, varscan2
- MMP19 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.692); catalogued as COSV59453480; called by muse, mutect2, varscan2
- NUMA1 | c.5668G>A p.G1890R | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs767774866, COSV52622866; called by muse, mutect2, varscan2
- OR52R1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100617799, COSV61888998; called by muse, mutect2, varscan2
- OR5M1 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101591537, COSV73202454; called by muse, mutect2, varscan2
- PCDHGB2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV54043492; called by muse, mutect2, varscan2
- PDGFRL | c.353+1G>A p.X118_splice | Splice Site (SNP) | VAF 37/112 reads (33%) | catalogued as rs1480843932, COSV52415570; called by muse, varscan2
- PEX14 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); catalogued as COSV63060816, COSV63063915; called by muse, mutect2, varscan2
- PLIN2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52804536; called by muse, mutect2, varscan2
- POTEH | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.576); catalogued as rs754486088, COSV100624793, COSV100624911; called by muse, mutect2, varscan2
- PPFIA4 | c.2657G>A p.R886H (on ENST00000447715; = p.R887H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373538808, COSV99691202; called by muse, mutect2, varscan2
- RANBP6 | c.1360C>A p.L454M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52391762; called by muse, mutect2, varscan2
- RBAK | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1345120337, COSV62332626; called by muse, mutect2, varscan2
- SLC44A1 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs780698255, COSV66027486; called by muse, mutect2, varscan2
- TBC1D32 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377465896; called by muse, mutect2, varscan2
- TET3 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.31); catalogued as COSV59882792; called by muse, mutect2, varscan2
- TEX29 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as COSV52097065; called by muse, mutect2, varscan2
- THNSL1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV64480012; called by muse, mutect2, varscan2
- TIPARP | c.1672A>G p.M558V | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as rs766769030, COSV55815866; called by muse, mutect2, varscan2
- TRPC4AP | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs146813768; called by muse, mutect2, varscan2
- VPS8 | c.2842G>A p.G948R (on ENST00000625842 / NM_001349294.1; = p.G946R on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/198 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.544); catalogued as rs766714213, COSV54997528; called by muse, mutect2, varscan2
- CABS1 | c.525C>T p.D175= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs541997419, COSV56734707; called by muse, mutect2, varscan2
- ITIH6 | c.3396G>A p.P1132= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as rs917219668, COSV54495308; called by muse, mutect2, varscan2
- MC3R | c.519C>T p.G173= | Silent (SNP) | VAF 68/170 reads (40%) | catalogued as COSV54765103; called by muse, mutect2, varscan2
- MYF6 | c.69G>A p.Q23= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV57353577; called by muse, mutect2, varscan2
- PPM1D | c.759C>T p.H253= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as rs749755269, COSV59958303; called by muse, mutect2, varscan2
- PTPRB | c.1365G>A p.L455= | Silent (SNP) | VAF 46/245 reads (19%) | catalogued as COSV54252464, COSV54255214; called by muse, mutect2, varscan2
- TAL1 | c.624C>T p.A208= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs780848420, COSV53748403; called by muse, mutect2, varscan2
- TSHZ2 | c.237C>T p.A79= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as rs781424430, COSV61587878; called by muse, mutect2, varscan2
- TTN | c.3318C>T p.G1106= (on ENST00000591111; = p.G1060= on NM_003319.4) | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as rs141768043; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- ANKRD20A5P | n.272G>T | RNA (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- KRTAP6-2 | c.-1G>A | 5'UTR (SNP) | VAF 41/95 reads (43%) | catalogued as rs1302409762, COSV58182247; called by muse, mutect2, varscan2
- N4BP2L1 | c.-1C>T | 5'UTR (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100583086, COSV100583124; called by muse, mutect2, varscan2
- TTN | c.34354+424G>A | Intron (SNP) | VAF 7/10 reads (70%) | catalogued as rs1060500468; ClinVar: uncertain significance; called by mutect2, varscan2
